Surgical pathology report (de-identified scan), TCGA case TCGA-5M-AAT6, project TCGA-COAD (Colon Adenocarcinoma), tissue source site University of Sao Paulo, specimen TCGA-5M-AAT6-01A (Primary Tumor).

Date:

SPECIMEN: Terminal ileum, cecum, appendix, ascending and transverse colon
PROCEDURE: Right hemicolectomy

MACROSCOPY

- Product of right hemicolectomy.
- Segment of terminal ileum, cecum, segment of ascending colon and appendix.
- The serosa is focally irregular, and displays multiple nodules in addition to a perforation 2.0 x 1.5 cm large, which is continuous to an ulcerative, vegetative luminal lesion measuring 8.0 x 8.0 cm, located 8.0 cm from the nearest surgical margin.
- The lesion penetrates the colon wall to the serosa.
- 11 lymph nodes were dissected from the pericolic fat; sizes ranging from 0.3 to 0.6 cm.

MICROSCOPIC EXAMINATION

- Moderately differentiated tubular adenocarcinoma of the ascending colon;
- Microscopic tumor extension: invasion of pericolic soft tissues;
- Perineural invasion: present;
- Lymph-vascular invasion: present;
- Moderate desmoplastic stromal reaction;
- Surgical margins free of neoplastic involvement;
- Number of lymph nodes examined: 11;
- Number of lymph nodes involved: 10;
- Stage: pT4c/d, pN2

PATHOLOGISTS

CLUE ICD-O-3
path Adenocarcinoma NOS 8140/3
Adenocarcinoma, tubular 8211/3
Site: Ascending colon C18.2
p 2/1/14

Source: NCI Genomic Data Commons file 4328dc1f-55f1-48ca-8e37-9bdd266d7da3 (TCGA-5M-AAT6.B25D2818-B3C6-49F0-81E6-224488C1E926.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).